CCDI case PBCBWN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/820f8fa7-f364-412d-83a2-f4be20b48473

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 13.9 years (5,077 days).

Biospecimens (3 samples)
- Sample 0DOO1H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOO1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOOCT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
